Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0AM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0AM-01A (Primary Tumor).

TSS Patient ID

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative ductal carcinoma

Date of Procurement: Anatomic Site: Left Breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Radical mastectomy Grade: 2

T Stage: 2 N Stage: 0 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement:

ICD-O-3
carcinoma, infiltrating duct, NOS 8500/3
site: breast, NOS C50.9 lw 10/21/11

Source: NCI Genomic Data Commons file 4a29db2c-638b-4a54-b475-7b3c5350cf85 (TCGA-AN-A0AM.7189A8A8-EB8B-4795-B7FE-725CCC4B7FA7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).